Surgical pathology report (de-identified scan), TCGA case TCGA-WK-A8XS, project TCGA-SARC (Sarcoma), tissue source site Brigham and Women's Hospital, specimen TCGA-WK-A8XS-01A (Primary Tumor).

[page 1 of 2]
Sex: F

Pathology Report

Accession Number:
Type: Surgical Pathology
Specimen Type: Stomach
Procedure Date:
Ordering Provider:

Report Status: Final

CASE:
PATIENT: XXXXXXXXXX

ICD O-3
Leiomyosarcoma NOS 8890/3
Site: Stomach NOS C16.9
J 5/6/14

Resident:
Pathologist:

PATHOLOGIC DIAGNOSIS:

SPECIMEN DESIGNATED "PARTIAL GASTRECTOMY":
LEIOMYOSARCOMA (7.6 cm), intermediate grade,
involving gastric mucosa and serosa; see NOTE.
Mitoses number up to 21:10 HPF.
No tumor necrosis identified.
Mucosal resection margins, negative for tumor.
Tumor is present 2.3 cm from the closest/proximal resection
margin.
Fundic gland polyp.

NOTE: The histologic findings are similar to the previous biopsy

CLINICAL DATA:

History: Gastric leiomyosarcoma - bleeding.
Operation: Partial gastrectomy.
Operative Findings: None specified.
Clinical Diagnosis: Bleeding gastric leiomyosarcoma.

TISSUE SUBMITTED:

A/1) Partial gastrectomy; short stitch - proximal; long stitch - anterior.

GROSS DESCRIPTION:

The specimen was received fresh, labeled with the patient's name, unit number, and "#1. Partial gastrectomy, short proximal, long anterior", and consists of one partial gastrectomy specimen (10.0 x 5.1 x 4.5 cm) designated with a short stitch (proximal) and a long stitch (anterior). One stapled resection margin spans distal to proximal (14.5 cm, inked in black). A tan/white/pink, firm, fungating mass (7.6 cm x 5.3 x 4.3 cm) is present in the gastric wall, 2.3 cm to closest resection margin (proximal). The cut surface of the tumor is tan/white and whorled, with punctate yellow foci of possible necrosis. Tumor extends to the serosa. Gross photographs are taken in the frozen section room. Representative tumor is submitted to cytogenetics. Representative sections of tumor and normal stomach are submitted to tissue bank and Dr. lab. No candidate lymph nodes are identified.

Micro A1: Tumor with proximal anterior resection margin, 1 frag,
Micro A2: Proximal posterior resection margin, 1 frag,
Micro A3: Tumor with distal anterior resection margin, 1 frag,
Micro A4: Distal posterior resection margin, 1 frag,
Micro A5-A6: Tumor with deepest extent of invasion, 1 frag each,
Micro A7: Tumor with necrosis, 1 frag,
Micro A8: Tumor with necrosis, 1 frag,
Micro A9: Tumor with normal mucosa, 1 frag,
Micro A10: Normal mucosa, 1 frag,
Micro A11: Candidate lymph nodes, 3 frags,

CASE NUMBER:

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[page 2 of 2]
~~XXXXXXXXXX~~
~~XXXXXXXXXX~~

Sex: F

Pathology Report

Final Diagnosis by

Electronically signed on

hw 12/11/13

SCD *12/13*

Source: NCI Genomic Data Commons file 69d5474a-c5ac-4ea4-bacb-c86a5e4d8df3 (TCGA-WK-A8XS.1D900310-E343-4B67-BE32-C00F8C0DC287.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).